Gene-level copy-number profile of tumor specimen TCGA-61-2098-01A from TCGA case TCGA-61-2098, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.6 years (22,876 days).
Specimen TCGA-61-2098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.89f4b51d-2c3d-4a66-8580-cb1edb8bb072.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,726 have no estimate.
https://portal.gdc.cancer.gov/files/f1498f89-b26b-493e-81ae-8f885c127f0a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 447; copy number 2: 13,374; copy number 3: 19,632; copy number 4: 14,221; copy number 5: 5,864; copy number 6: 1,102; copy number 8: 229; copy number 10: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-61-2098-01): tumor purity 0.85, ploidy 3.34, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 256 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:490,944–17,817,798, 255 genes, copy number 8–10 (broad region; genes not listed).
- chr2:18,040,606–18,040,733, 1 gene, copy number 8: AC079802.1.

Autosomal genes at a single copy (total copy number 1): 447. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
